TCGA case TCGA-GZ-6640 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Hematopoietic and reticuloendothelial systems; Tissue source site: BC Cancer Agency.
https://portal.gdc.cancer.gov/cases/44f10972-9f1f-4f7d-b8a0-0062c961001b

Biospecimens (2 samples)
- Samples TCGA-GZ-6640-10A, TCGA-GZ-6640-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
